Gene-level copy-number profile of tumor specimen TCGA-86-8054-01A from TCGA case TCGA-86-8054, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.8 years (22,584 days).
Specimen TCGA-86-8054-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.d8b4d40c-1925-4fcb-9c09-58e4cc3c43cf.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8054-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 416 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3a442b14-2ee7-4911-b43e-78a6c05ceafd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,470; copy number 2: 21,620; copy number 3: 26,410; copy number 4: 4,917; copy number 5: 2,391; copy number 6: 957; copy number 7: 741; copy number 8: 79; copy number 9: 332; copy number 10: 150; copy number 11: 109; copy number 12: 15; copy number 13: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8054-01A-11D-2237-01): tumor purity 0.74, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr14:44,507,385–44,567,467, 1 gene (within-gene range 0–2): AL356022.1.
- chr17:41,271,311–41,276,697, 2 genes (within-gene range 0–3): KRTAP9-11P, KRTAP9-7.
- chr19:20,340,269–20,424,969, 1 gene (within-gene range 0–2): ZNF826P.
- chr19:20,389,658–20,571,095, 5 genes (within-gene range 0–2): AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,431 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–148,288,951, 156 genes, copy number 10–11 (broad region; genes not listed).
- chr1:148,295,180–148,344,638, 6 genes, copy number 11 (within-gene range 6–11): LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr1:167,809,386–169,485,944, 42 genes, copy number 7 (within-gene range 4–7): ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1.
- chr3:179,396,088–179,627,647, 11 genes, copy number 8: GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1.
- chr4:14,111,968–14,143,592, 2 genes, copy number 8: LINC01085, AC073848.1.
- chr4:30,718,805–30,721,970, 1 gene, copy number 8: AC098595.1.
- chr4:38,276,178–38,572,022, 7 genes, copy number 9: AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278.
- chr4:38,618,265–38,619,437, 1 gene, copy number 9: AC021860.1.
- chr4:51,843,000–52,551,574, 9 genes, copy number 8 (within-gene range 4–8): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2.
- chr4:55,948,871–56,388,153, 9 genes, copy number 9 (within-gene range 4–9): CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1.
- chr8:53,493,523–85,828,467, 497 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr9:33,921,693–34,048,949, 1 gene, copy number 7 (within-gene range 2–7): UBAP2.
- chr9:33,952,769–34,311,371, 13 genes, copy number 7 (within-gene range 4–7): SNORD121A, OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24.
- chr11:55,262,155–56,038,191, 53 genes, copy number 7–10: TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1, TRIM51, OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1.
- chr14:34,920,858–41,149,309, 103 genes, copy number 7–11 (broad region; genes not listed).
- chr14:41,514,972–41,904,549, 6 genes, copy number 10–13: AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1.
- chr17:14,947,741–21,419,870, 348 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr20:87,250–2,341,079, 71 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:3,082,556–3,410,036, 15 genes, copy number 12: AVP, RN7SL555P, UBOX5-AS1, UBOX5, FASTKD5, LZTS3, DDRGK1, ITPA, SLC4A11, AL109976.1, C20orf194, RNU6-1019P, UBE2V1P1, U3, AL117334.1.
- chr20:55,074,644–55,781,231, 6 genes, copy number 8–11: RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1.
- chr20:57,351,223–57,379,211, 1 gene, copy number 9 (within-gene range 5–9): RAE1.
- chr20:57,358,447–60,653,784, 73 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 93. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
